Somatic mutation profile of tumor specimen TCGA-LN-A49K-01A (aliquot TCGA-LN-A49K-01A-11D-A247-09) from TCGA case TCGA-LN-A49K, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 66.7 years (24,379 days).
Specimen TCGA-LN-A49K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 290a5efe-0416-4ad9-98de-cf5fd9f806de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A49K-10A (Blood Derived Normal), aliquot TCGA-LN-A49K-10A-01D-A247-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56507c75-d283-4ac6-87e0-267c7157eab1

The open-access MAF lists 87 somatic variants for this specimen: 68 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 17, Nonsense Mutation 3, Frame Shift Del 3, Intron 2, Nonstop Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.4913C>T p.P1638L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV101239197, COSV67141911; called by muse, mutect2, varscan2
- ARMC4 | c.2507G>A p.R836H | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.133); catalogued as rs376281682; called by muse, varscan2
- BTN2A2 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV61858476; called by muse, mutect2
- CELSR2 | c.6491C>T p.T2164M | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775752921, COSV54765919; called by muse, mutect2, varscan2
- CTNND2 | c.2666G>T p.R889L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58869532; called by muse, mutect2, varscan2
- CUL3 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52368277; called by muse, mutect2, varscan2
- DAGLA | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV57194880; called by muse, mutect2, varscan2
- DEPDC5 | c.2300G>T p.R767L (on ENST00000400246; = p.R836L on NM_014662.5) | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as rs1396979413, COSV56708649; called by muse, mutect2
- DIO2 | c.43C>A p.L15M | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV70444962; called by muse, mutect2, varscan2
- FOXD4L6 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.05); catalogued as rs1340827419; called by mutect2, varscan2
- GRIK4 | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs139636929; called by muse, mutect2, varscan2
- HID1 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); catalogued as rs141799560; called by muse, mutect2, varscan2
- HMCN1 | c.2412G>A p.M804I | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1371971425; called by muse, mutect2, varscan2
- KCTD21 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs370613583, COSV60740668; called by muse, mutect2, varscan2
- KPNB1 | c.1656G>T p.L552F | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as COSV51595251; called by muse, mutect2
- LZTR1 | c.1540C>T p.R514W | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs779673877, COSV99302096; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MICU2 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs140786216; called by muse, mutect2, varscan2
- MORC2 | c.2950G>A p.E984K (on ENST00000397641 / NM_001303256.3; = p.E922K on NM_014941.3) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs773617883; called by muse, mutect2, varscan2
- MOV10 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as rs748592404; called by muse, mutect2, varscan2
- OGDH | c.2032G>A p.V678M | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139641350; called by muse, mutect2, varscan2
- PRCP | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV57291178; called by muse, mutect2, varscan2
- PRKCH | c.26A>G p.N9S | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.019); catalogued as rs371540089; called by muse, mutect2, varscan2
- RTN1 | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs765134472, COSV50719589; called by muse, mutect2, varscan2
- RUNX1T1 | c.1810C>T p.R604C (on ENST00000265814 / NM_001198628.1; = p.R577C on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1221874209, COSV56155283, COSV99749432; called by muse, mutect2, varscan2
- TBC1D22A | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs988342620; called by muse, mutect2
- TP53 | c.365_366del p.V122Dfs*26 | Frame Shift Del (DEL) | VAF 27/59 reads (46%) | catalogued as rs587780067; called by pindel, varscan2
- TRERF1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.103); catalogued as rs201248674; called by muse, mutect2, varscan2
- TRIM23 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs915022414, COSV51549840; called by muse, mutect2, varscan2
- ULK2 | c.2320G>A p.G774S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV64444482; called by muse, mutect2
- ZNF318 | c.6343C>T p.R2115C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.459); catalogued as rs141160354; called by muse, varscan2
- ZNF565 | c.484G>A p.E162K (on ENST00000355114; = p.E122K on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767613413, COSV58411747; called by muse, varscan2
- AMPH | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2
- ARL14EP | c.781T>A p.*261Kext*15 | Nonstop Mutation (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2
- B3GALT2 | c.957T>A p.F319L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.075); called by mutect2, varscan2
- CASD1 | c.1592C>G p.T531S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- CCDC39 | c.1007A>T p.K336M | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CCDC88A | c.1621A>T p.T541S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CCDC88B | c.838C>A p.L280M | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.827); called by muse, mutect2
- CCT7 | c.491G>T p.S164I | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- DLGAP3 | c.2373C>A p.C791* | Nonsense Mutation (SNP) | VAF 3/10 reads (30%) | called by muse, varscan2
- DYNC1H1 | c.3022G>T p.V1008L | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FLT1 | c.1979C>A p.A660E | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- GANAB | c.1519G>T p.A507S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IL12RB2 | c.2045del p.E682Gfs*12 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel, varscan2
- KIF3A | c.1920G>T p.E640D | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- LRGUK | c.652A>C p.T218P | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- LRRC7 | c.2921T>A p.M974K (on ENST00000651989 / NM_001370785.2; = p.M941K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.957); called by muse, mutect2
- LYPLA1 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- MAP3K10 | c.783G>T p.M261I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- MDGA2 | c.2270T>A p.I757N (on ENST00000399232 / NM_001113498.2; = p.I459N on NM_182830.4) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOS3 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OLFML2B | c.1523A>G p.N508S | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- OR1J1 | c.69G>T p.Q23H | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- OR4F5 | c.864G>C p.K288N | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.104); called by mutect2, varscan2
- OR5AU1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- PARP8 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- PLTP | c.425C>A p.S142Y | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2
- PTER | c.1015del p.I339* | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- QSOX1 | c.2055G>T p.Q685H | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2
- SIN3A | c.3533A>G p.Y1178C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SLCO1B1 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- SMG1 | c.9572A>T p.Q3191L | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.242); called by muse, mutect2
- SRCAP | c.6494G>C p.R2165T | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- SYTL4 | c.436+1G>A p.X146_splice | Splice Site (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2
- TLN1 | c.6232G>A p.V2078M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- TMEM181 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.013); called by mutect2, varscan2
- TNFSF10 | c.111C>A p.Y37* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2
- TP53BP2 | c.2635C>A p.P879T (on ENST00000343537 / NM_001031685.3; = p.P750T on NM_005426.2) | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AMBRA1 | c.1767T>C p.P589= (on ENST00000458649 / NM_001367468.1; = p.P499= on NM_017749.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- ATAD3B | c.222C>T p.A74= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV100426443; called by muse, mutect2, varscan2
- F9 | c.966C>T p.D322= | Silent (SNP) | VAF 46/55 reads (84%) | catalogued as rs373107855, COSV99496345; called by muse, mutect2, varscan2
- FNDC1 | c.366T>G p.P122= | Silent (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- HMGN5 | c.180C>A p.A60= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs1462069697, COSV63916442; called by muse, mutect2, varscan2
- LRP2 | c.10803C>T p.C3601= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as rs370876114; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR10A6 | c.747C>G p.T249= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV59166059; called by muse, mutect2, varscan2
- OR10Z1 | c.390C>A p.L130= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV63525987, COSV63526723; called by muse, mutect2, varscan2
- PTPRO | c.2574T>C p.G858= | Silent (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- RPAP1 | c.147G>A p.P49= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs1055364267, COSV100427382, COSV58543090; called by muse, mutect2
- SCN11A | c.759G>T p.L253= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100181623; called by mutect2, varscan2
- SPAM1 | c.492C>T p.Y164= | Silent (SNP) | VAF 8/22 reads (36%) | called by muse, varscan2
- SPATA16 | c.1089A>G p.Q363= | Silent (SNP) | VAF 23/101 reads (23%) | called by muse, varscan2
- TEX10 | c.2619C>T p.L873= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs191855673, COSV52440462; called by muse, mutect2, varscan2
- TMEM37 | c.465C>T p.L155= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs1267163701; called by muse, mutect2, varscan2
- TTN | c.10566G>A p.L3522= (on ENST00000591111; = p.L3476= on NM_003319.4) | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV59978736; called by muse, mutect2
- VPS4B | c.267A>G p.E89= | Silent (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2, varscan2
- DMD | c.1331+2624A>G | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as COSV55885548; called by muse, mutect2
- MARK4 | c.1877+216G>C | Intron (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
